Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7654, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7654-01A (Primary Tumor).

[page 1 of 3]
HISTOPATHOLOGY REPORT

Inquiry Number:

Division Head:

ORIGINAL REPORT

SPECIMEN:

- A. Portal lymph node.
- B. Node of importance.
- C. Gallbladder.
- D. Whipple's specimen.

CLINICAL HISTORY:

Mass head of pancreas.

DIAGNOSIS:

A. PORTAL LYMPH NODE:
- REACTIVE CHANGES ONLY.

B. NODE OF IMPORTANCE:
- REACTIVE CHANGES ONLY.

C. GALLBLADDER:
- LYMPHOCYTIC CHOLECYSTITIS WITH CHOLELITHIASIS.

D. WHIPPLE'S SPECIMEN:
- MODERATELY DIFFERENTIATED PANCREATIC DUCTAL CARCINOMA, 3.0 CM IN
GREATEST DIMENSION WITH LYMPHATIC AND INTRANEURAL INVASION, RESECTION
MARGINS UNINVOLVED BY TUMOR.
- THREE PERIPANCREATIC NODES, METASTATIC DUCTAL CARCINOMA IN 2/3 WITH
EXTRANODAL EXTENSION.

FINAL

[page 2 of 3]
HISTOPATHOLOGY REPORT

Inquiry Numbers:

Division Head:

GROSS DESCRIPTION:

A. The specimen is received fresh and is subsequently placed into formalin, and consists of a tan to brown irregular portion of tissue measuring 0.7 cm in greatest dimension. Submitted in toto in one cassette.

B. The specimen is received fresh and is subsequently placed into formalin, and consists of a tan to black irregular portion of tissue measuring 1.0 cm in greatest dimension and submitted in toto in one cassette.

C. The specimen is received fresh and is subsequently placed into formalin, and consists of a pink, tan intact gallbladder which measures 6.5 x 3.0 x 2.0 cm. The serosal surface is smooth and glistening. Opening the gallbladder reveals a clear mucinous bile and two yellow green ovoid calculi both measuring approximately 1.5 cm in greatest dimension. The mucosal surface is tan, rough and the gallbladder wall measures 0.3 cm in thickness. The cystic duct is patent and grossly the cystic duct lymph node is not identified. Three representative sections of the gallbladder are submitted in one cassette.

D. The specimen is received fresh and is subsequently placed into formalin, and consists of a segment of small bowel and attached head of pancreas. Grossly, there may be a very small segment of the most distal portion of stomach. The small bowel measures 24.0 cm in length and has an average circumference of 6.0 cm. The attached head of pancreas is firm upon palpation and measures 5.0 x 4.5 x 3.5 cm. Attached to the head of pancreas near the bile duct margin are two black nodular structures ?lymph nodes. One measuring 0.5 cm and the other measuring 0.5 cm in greatest dimension. Opening of the bowel reveals a dark tan exophytic mass at the ampulla of Vater. This mass measures 1.5 x 1.0 cm. The rest of the bowel mucosa appears unremarkable. Sectioning of the head of the pancreas reveals a tan fibrotic ill-defined mass with a cystic component. This mass grossly appears to measure 2.5 x 2.0 x 3.0 cm. The cyst containing clear mucin and ranges from 0.2 to 0.3 cm in greatest dimension. Opening of the bile duct grossly reveals this mass within the pancreas to erode through the bile duct. The most distal portion of the bile duct, however, grossly appears unremarkable. Section of the specimen are as follows:

- D1. what is believed to be pancreatic margin
- D2. bile duct margin
- D3-4. proximal margin bisected
- D5. distal margin bisected
- D6-7. longitudinal section through the bile duct and ampulla moving from

FINAL

[page 3 of 3]
HISTOPATHOLOGY REPORT

Inquiry Number:

Division Head:

GROSS DESCRIPTION:

- D8. ampulla towards distal portion of bile duct
- D9. longitudinal section through what was grossly believed to be pancreatic margin and pancreatic duct
- D9. section of firm ill-defined mass with cystic areas in pancreas
- D10-11. two sections of pancreas away from the mass, but grossly still has a irregular appearance
- D12. three previously described lymph nodes
- D13. random section of bowel mucosa proximal to the ampulla
- D14. random section of bowel mucosa distal to the ampulla

FINAL

Source: NCI Genomic Data Commons file a2000325-9b40-4e48-b021-dde301eddcae (TCGA-IB-7654.1E1548DE-1985-4423-85FA-2D80FCE62D06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).